Gene-level copy-number profile of tumor specimen HTMCP-02-01-01256-01A from CGCI case HTMCP-02-01-01256, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV.
Specimen HTMCP-02-01-01256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 510472e2-0bc2-4dc2-a92d-e76a2b84ea89.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01256-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/2c921557-a54a-4caf-920e-fcb29e44df4b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 236; copy number 1: 2,201; copy number 2: 14,294; copy number 3: 20,441; copy number 4: 13,449; copy number 5: 4,390; copy number 6: 2,221; copy number 7: 645; copy number 8: 447; copy number 9: 2; copy number 18: 3; copy number 22: 10; copy number 38: 6; copy number 39: 10; copy number 48: 27.

Homozygous deletions (total copy number 0; autosomes only): 236 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–18,910,950, 228 genes (broad region; genes not listed).
- chr17:46,503,946–46,509,339, 1 gene: RDM1P2.
- chr18:60,163,567–60,540,205, 5 genes (within-gene range 0–1): RNU4-17P, AC090771.1, AC090621.1, AC091576.1, MC4R.
- chr18:79,679,803–79,754,510, 2 genes: CTDP1, AC068473.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,150 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,498,665–113,501,155, 1 gene, copy number 7: FOXD4L1.
- chr4:1,982,717–2,041,903, 1 gene, copy number 7 (within-gene range 4–7): NELFA.
- chr5:23,262,159–36,867,238, 178 genes, copy number 7–8 (broad region; genes not listed).
- chr7:45,769,105–45,815,263, 2 genes, copy number 7 (within-gene range 4–7): GTF2IP13, RNU6-241P.
- chr7:150,603,561–150,604,644, 1 gene, copy number 9: AC069304.3.
- chr8:38,382,364–38,383,461, 1 gene, copy number 7: AC087623.2.
- chr8:41,032,892–41,032,998, 1 gene, copy number 7: RNU6-356P.
- chr8:91,209,494–130,017,129, 552 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr9:97,200,475–97,238,745, 2 genes, copy number 7 (within-gene range 3–7): AL590705.1, AL590705.2.
- chr10:11,823,339–29,318,328, 290 genes, copy number 7 (broad region; genes not listed).
- chr10:31,693,084–35,231,394, 58 genes, copy number 7: MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P.
- chr10:43,523,256–43,525,217, 1 gene, copy number 9: AL450326.2.
- chr10:45,615,500–45,792,964, 5 genes, copy number 7: ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C.
- chr12:12,310–2,697,950, 56 genes, copy number 18–48 (within-gene range 4–48): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3.
- chr19:50,152,548–50,163,195, 1 gene, copy number 8: IZUMO2.

Autosomal genes at a single copy (total copy number 1): 2,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
